Somatic mutation profile of tumor specimen ALCH-B4EV-TTP1-A (aliquot ALCH-B4EV-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4EV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.5 years (22,104 days).
Specimen ALCH-B4EV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68ce454c-1cc4-4de0-b7c3-31391b424372.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4EV-NB1-A (Blood Derived Normal), aliquot ALCH-B4EV-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e87b5942-fefc-4eba-9af3-2bbeb7f5e32e

The open-access MAF lists 47 somatic variants for this specimen: 30 protein-altering or splice-affecting, 13 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 13, Frame Shift Del 2, 5'Flank 2, Translation Start Site 1, Nonsense Mutation 1, In Frame Del 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 193/784 reads (25%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- C1orf94 | c.1361C>A p.A454E (on ENST00000488417 / NM_001134734.2; = p.A264E on NM_032884.5) | Missense Mutation (SNP) | VAF 151/852 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as rs751301476; called by muse, mutect2, varscan2
- FAM110C | c.151C>G p.R51G | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.308); catalogued as COSV59656781; called by muse, mutect2, varscan2
- KIF16B | c.2189T>C p.L730P | Missense Mutation (SNP) | VAF 16/436 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1182925164; called by muse, mutect2
- KLK4 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 73/402 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV100133530, COSV60676342; called by muse, mutect2, varscan2
- LAMA3 | c.4159C>G p.R1387G | Missense Mutation (SNP) | VAF 76/759 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV100558062; called by muse, mutect2, varscan2
- MUC16 | c.39724C>T p.R13242C | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.963); catalogued as rs749823098, COSV66695315; called by muse, mutect2
- NLRC5 | c.3161G>A p.R1054Q | Missense Mutation (SNP) | VAF 56/758 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs377396638; called by muse, mutect2
- OR5M10 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 55/229 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs745900127, COSV73242480; called by muse, mutect2, varscan2
- PCNX3 | c.3970C>T p.R1324C | Missense Mutation (SNP) | VAF 36/494 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs775804738; called by muse, mutect2
- ROBO2 | c.2744A>G p.N915S | Missense Mutation (SNP) | VAF 110/541 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as rs980059108; called by muse, mutect2, varscan2
- ZNF780A | c.1784G>A p.R595Q | Missense Mutation (SNP) | VAF 56/280 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.22); catalogued as rs1241311085, COSV61816020; called by muse, mutect2, varscan2
- ABHD18 | c.-6_4del | Translation Start Site (DEL) | VAF 26/183 reads (14%) | called by mutect2, pindel, varscan2
- ALX1 | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 16/426 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.414); called by muse, mutect2
- CCDC146 | c.1759G>T p.D587Y | Missense Mutation (SNP) | VAF 67/329 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CELSR3 | c.4235C>A p.P1412H | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CFAP46 | c.6713A>G p.Y2238C | Missense Mutation (SNP) | VAF 73/305 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- CLPTM1L | c.1556G>C p.R519T | Missense Mutation (SNP) | VAF 11/375 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DFFA | c.408del p.S137Afs*87 | Frame Shift Del (DEL) | VAF 139/625 reads (22%) | called by mutect2, pindel, varscan2
- ELMO1 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 68/432 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NRK | c.4147G>T p.D1383Y | Missense Mutation (SNP) | VAF 18/581 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2
- NSD3 | c.1457A>G p.H486R | Missense Mutation (SNP) | VAF 42/456 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.077); called by muse, mutect2
- PDZD4 | c.42G>T p.Q14H | Missense Mutation (SNP) | VAF 26/518 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2
- PIWIL2 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 48/528 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- PREX2 | c.1653_1654del p.S552Rfs*5 | Frame Shift Del (DEL) | VAF 42/350 reads (12%) | called by mutect2, pindel, varscan2
- PRIMPOL | c.1180A>T p.K394* | Nonsense Mutation (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- PRR32 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 22/524 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.023); called by muse, mutect2
- RREB1 | c.2734G>C p.V912L | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- SPPL3 | c.86T>A p.V29D | Missense Mutation (SNP) | VAF 53/222 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.305); called by muse, varscan2
- TENM4 | c.7979C>G p.T2660S | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ABCA12 | c.4096C>T p.L1366= (on ENST00000272895 / NM_173076.3; = p.L1048= on NM_015657.3) | Silent (SNP) | VAF 24/598 reads (4%) | called by muse, mutect2
- CFHR5 | c.846G>A p.P282= | Silent (SNP) | VAF 84/481 reads (17%) | catalogued as rs754917131; called by muse, mutect2, varscan2
- DCAF1 | c.615C>T p.P205= | Silent (SNP) | VAF 12/359 reads (3%) | called by muse, mutect2
- EIF4ENIF1 | c.1920A>T p.A640= | Silent (SNP) | VAF 20/278 reads (7%) | called by muse, mutect2
- MIB2 | c.477C>T p.S159= | Silent (SNP) | VAF 19/163 reads (12%) | catalogued as rs1472822072; called by muse, mutect2, varscan2
- MICAL2 | c.2619T>G p.A873= | Silent (SNP) | VAF 43/385 reads (11%) | called by muse, mutect2, varscan2
- PAX7 | c.1386C>T p.Y462= | Silent (SNP) | VAF 119/216 reads (55%) | catalogued as rs570561092, COSV64751276; called by muse, mutect2, varscan2
- PNPO | c.516G>A p.V172= (on ENST00000225573; = p.V215= on NM_018129.4) | Silent (SNP) | VAF 28/670 reads (4%) | catalogued as rs1567714119; called by muse, mutect2
- PRB4 | c.591C>T p.P197= | Silent (SNP) | VAF 32/99 reads (32%) | called by muse, mutect2, varscan2
- PRPS1L1 | c.6G>A p.P2= | Silent (SNP) | VAF 82/467 reads (18%) | catalogued as rs1169327133; called by muse, mutect2, varscan2
- SLITRK1 | c.957C>A p.I319= | Silent (SNP) | VAF 58/321 reads (18%) | catalogued as rs1450521316; called by muse, mutect2, varscan2
- SNTA1 | c.9C>T p.S3= | Silent (SNP) | VAF 33/119 reads (28%) | called by muse, mutect2, varscan2
- TNPO2 | c.1434G>A p.L478= | Silent (SNP) | VAF 24/552 reads (4%) | catalogued as rs951525929; called by muse, mutect2
- AP000769.5 | chr11:65498989 T>C | 5'Flank (SNP) | VAF 89/424 reads (21%) | catalogued as rs754397792; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500255 del TTAG | 5'Flank (DEL) | VAF 28/318 reads (9%) | called by mutect2, pindel
- ERCC6 | c.1527-38G>A | Intron (SNP) | VAF 28/460 reads (6%) | called by muse, mutect2
- SSTR5-AS1 | n.943C>T | RNA (SNP) | VAF 12/362 reads (3%) | called by muse, mutect2
